Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XH, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XH-01A (Primary Tumor).

[page 1 of 2]
Procedure

Received

Report Site

Final Diagnosis:

A. Brain, left frontal lesion, biopsy: Low-grade oligoastrocytoma (WHO grade II).

Special stains:

MIB-1/Ki67: Low labeling index.

p53: Low labeling index.

GFAP: A subset of tumor cells are positive.

Fluorescence in situ hybridization (FISH) studies for 1p/19q deletions have been ordered on paraffin sections and will be performed by the

1CD-0-3

Oligoastrocytoma 9382/3

Site: Brain, frontal lobe C71-1

fw
10/23/12

[page 2 of 2]
Preliminary Frozen Section Consultation:

A. Brain, left frontal lesion, smears: Glial neoplasm. Hold over to classify.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "left frontal lesion" is an 8.3 x 5.9 x 2.8 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

Block Summary:

Part A: Left frontal lesion- left brain

- 1 Lt frontal lesion
- 2 Lt frontal lesion 2
- 3 Lt frontal lesion 3
- 4 Lt frontal lesion 4

D.

END OF REPORT

	Yes	No

Source: NCI Genomic Data Commons file 99e45eb0-c0ac-4b11-9958-9f865a3a778e (TCGA-DB-A4XH.5AD2C9F3-9A4A-4974-98F8-90AA632C1B8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).